CGCI case HTMCP-03-06-02333 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/18bce2c3-5060-4282-b7a0-11ada9a3eebf

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 47 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 47.6 years (17,396 days); Year of diagnosis: 2016; Method of diagnosis: Biopsy; AJCC clinical T: T2a1; FIGO stage: Stage IIA1; FIGO staging edition year: 2009; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 401 days (1.1 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Paclitaxel; Initial disease status: Initial Diagnosis; Days to treatment start: 387 days (1.1 years); Number of cycles: 1.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease; Surgery, NOS.

Follow-up (5 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 341 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 341 days.
- Days to follow up: 341 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Overlapping lesion of urinary organs; Days to recurrence: 341 days.
- Days to follow up: 356 days; Disease response: With Tumor.
- Days to follow up: 401 days (1.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day 0: Pregnancy outcome: Miscarriage.
- Day 0: Weight: 42.1 kg; Height: 159.1 cm; BMI: 16.6; Hormonal contraceptive use: Never Used; Hysterectomy type: Not Performed; Menopause status: Postmenopausal; Pregnant at diagnosis: No.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02333-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02333-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02333-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 8; Pregnancies count miscarriage: 3; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 11; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Squamous Cell Carcinoma, Keratinizing; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: HIV status: Negative.
- Follow-up form 2: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 2, New tumor event 1: New tumor event type: Locoregional Recurrence; New tumor event site: Lymph Node(s); New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form 2, New tumor event 2: New tumor event site other: Bladder/ureter; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: No; Pharmaceutical regimen: Paclitaxel + Cisplatin; Pharma adjuvant cycles count: 1.
